Somatic mutation profile of tumor specimen 0DQ8XS from CCDI case PBCENE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.0 years (2,188 days).
Specimen 0DQ8XS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48abf303-32d3-4e16-ac89-67ab019baaba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ8YC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5790db89-5c05-4448-ab49-eff9d5600081

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CATSPER3 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 245/486 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs145171708; called by muse, mutect2, varscan2
- POM121L2 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 205/483 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779874635, COSV66276775; called by muse, mutect2, varscan2
- RASGRP2 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs147886381, COSV100818282; called by muse, mutect2, varscan2
- RSPH6A | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 163/371 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550174347, COSV99537262; called by muse, mutect2, varscan2
- SACM1L | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 201/523 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV66612930; called by muse, mutect2, varscan2
- ZNF845 | c.1084A>G p.K362E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1239350099, COSV72004794; called by muse, mutect2
- HTT | c.8109+1G>T p.X2703_splice | Splice Site (SNP) | VAF 93/174 reads (53%) | called by muse, mutect2, varscan2
- PRR14 | c.1129C>A p.R377= | Silent (SNP) | VAF 23/170 reads (14%) | called by muse, mutect2, varscan2
- RNF8 | c.267A>G p.R89= | Silent (SNP) | VAF 169/401 reads (42%) | called by muse, mutect2, varscan2
- SLC25A41 | c.441C>T p.S147= | Silent (SNP) | VAF 78/150 reads (52%) | called by muse, mutect2, varscan2
- TRIM42 | c.804G>A p.S268= | Silent (SNP) | VAF 243/468 reads (52%) | catalogued as rs114287544; called by muse, mutect2, varscan2
- UBE3C | c.792C>T p.F264= | Silent (SNP) | VAF 70/762 reads (9%) | called by muse, mutect2
- CHRNB1 | c.1217+74C>A | Intron (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
